Somatic mutation profile of tumor specimen TARGET-40-0A4I3W-01A (aliquot TARGET-40-0A4I3W-01A-01D) from TARGET case TARGET-40-0A4I3W, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 19.2 years (7,023 days).
Specimen TARGET-40-0A4I3W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7df80733-0c94-4ef9-beb3-a97b648cdcfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I3W-10A (Blood Derived Normal), aliquot TARGET-40-0A4I3W-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20efda24-27d4-4237-a18f-885aaafc13f7

The open-access MAF lists 26 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, 5'UTR 2, Nonsense Mutation 2, Splice Region 1, 3'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCC | c.1675C>G p.Q559E | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.259); catalogued as COSV59104434; called by muse, mutect2, varscan2
- LRP1 | c.3667A>G p.I1223V | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.847); catalogued as rs1191788726; called by muse, mutect2, varscan2
- MUC16 | c.27910G>T p.E9304* | Nonsense Mutation (SNP) | VAF 50/823 reads (6%) | catalogued as COSV67451945; called by muse, mutect2
- OR4N2 | c.265A>C p.K89Q | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs1385363256; called by muse, mutect2
- PLG | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV51982117; called by muse, mutect2
- AP1G1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2
- ERC1 | c.1335G>C p.E445D | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HP1BP3 | c.846G>C p.R282S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MAGEC3 | c.1168A>T p.S390C | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- MAS1 | c.110G>A p.W37* | Nonsense Mutation (SNP) | VAF 39/146 reads (27%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCH1 | c.2114G>T p.G705V (on ENST00000340059 / NM_001130960.2; = p.G717V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SSU72 | c.364+3G>C | Splice Region (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- SUMF1 | c.389A>C p.E130A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- VPS13A | c.5653G>C p.G1885R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CASKIN2 | c.714G>A p.R238= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- FAM71F2 | c.672G>A p.A224= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as rs760732983, COSV66352042; called by muse, mutect2, varscan2
- KLHL17 | c.708A>G p.K236= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- RALGAPA1 | c.3063C>T p.D1021= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs1413591713, COSV51882950, COSV51902238; called by muse, mutect2, varscan2
- RYR3 | c.1731G>A p.A577= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs776461221, COSV66779569; called by muse, mutect2, varscan2
- SFTPC | c.39G>A p.P13= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs532360636, COSV59345248; called by muse, mutect2
- C7orf61 | c.*47G>A | 3'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2
- DPP6 | c.627+21146C>T | Intron (SNP) | VAF 47/134 reads (35%) | catalogued as rs769763674, COSV100122840; called by muse, mutect2, varscan2
- EI24P4 | n.947T>C | RNA (SNP) | VAF 14/263 reads (5%) | catalogued as rs751543353; called by muse, mutect2
- ITGA2B | c.-24C>T | 5'UTR (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- MRPS15 | c.-52C>A | 5'UTR (SNP) | VAF 9/22 reads (41%) | catalogued as rs1470553601; called by mutect2, varscan2
